Gene-level copy-number profile of tumor specimen TCGA-B1-7332-01A from TCGA case TCGA-B1-7332, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 61.0 years (22,277 days).
Specimen TCGA-B1-7332-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRP.db8bd3a1-4023-413f-bb0b-710f50b6e38c.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B1-7332-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 349 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c7b6b96f-67a3-4a44-a525-a6223251aace

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 21,925; copy number 1: 400; copy number 2: 23,963; copy number 3: 773; copy number 4: 13,180; copy number 5: 32; copy number 7: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-B1-7332-01A-11D-2135-01): tumor purity 0.74, ploidy 2.87, whole-genome doublings 1.

Caution: 21,405 autosomal genes are at 0 copies in this file, far more than a typical tumor; the lists below are given as recorded.

Homozygous deletions (total copy number 0; autosomes only): 21,405 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:3,976,133–248,919,946, 5,263 genes (within-gene range 0–2) (broad region; genes not listed).
- chr2:125,823,108–126,343,992, 5 genes: AC097499.1, LINC01941, AC142116.2, AC023347.1, SLC6A14P3.
- chr4:53,286–190,092,279, 2,654 genes (broad region; genes not listed).
- chr8:150,584–145,066,685, 2,481 genes (broad region; genes not listed).
- chr9:113,313,222–113,371,233, 2 genes (within-gene range 0–2): WDR31, BSPRY.
- chr11:3,599,595–135,075,908, 3,165 genes (broad region; genes not listed).
- chr13:57,204,379–57,204,799, 1 gene: MTCO2P3.
- chr14:18,333,726–106,875,071, 2,285 genes (broad region; genes not listed).
- chr18:47,390–80,247,514, 1,239 genes (broad region; genes not listed).
- chr19:94,062–58,605,223, 2,981 genes (broad region; genes not listed).
- chr22:16,405,330–25,252,602, 538 genes (broad region; genes not listed).
- chr22:25,561,117–50,801,309, 791 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 33 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:160,677,160–165,846,519, 32 genes, copy number 5 (within-gene range 4–5): ARL14, SNORA72, AC069224.1, PPM1L, B3GALNT1, NMD3, AC108738.1, EEF1GP4, PSMC1P7, SPTSSB, LINC02067, AC112491.1, RPL23AP42, OTOL1, AC112770.1, AC131211.1, TOMM22P6, AC128716.1, AC128685.1, LINC01192, RPS6P4, AC079910.1, RNU7-82P, AC084017.1, MIR1263, LINC01323, LINC01324, SI, Y_RNA, LINC02023, SLITRK3, LINC01322.
- chr7:71,685,452–71,685,747, 1 gene, copy number 7: RN7SKP75.

Autosomal genes at a single copy (total copy number 1): 397. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
